Surgical pathology report (de-identified scan), TCGA case TCGA-4Z-AA86, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-4Z-AA86-01A (Primary Tumor).

ICD-O-3
Carcinoma, urothelial NOS
C67.1
Site Bladder dome
path Bladder NOS
C67.9
8/20/13
12/31/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Bladder

1 - "Appendix":

Chronic nonspecific periappendicitis.

Absence of neoplasia in the analyzed material.

2 - "Prostate + seminal vesicles + bladder":

Urothelial cell carcinoma of high-grade characterized as follows:

Measure of neoplasia in its major axis: 5.0 cm.

Infiltration of the whole thickness of the bladder wall and adjacent perivesical fat.

Ulceration present.

Perforation of the bladder peritoneum with formation of fistulae in the perivesical fat.

Neural infiltration not observed.

Lymphatic vascular invasion present.

Sanguineous vascular invasion not detected.

Prostate and seminal vesicles free of neoplastic involvement.

Surgical margins free of neoplastic involvement.

3 - "Left iliac obturator lymph nodes":

Urothelial carcinoma metastatic to one lymph node without capsular perforation (1/7).

4 - "Right iliac obturator lymph nodes":

Free of neoplastic involvement (0/8).

Source: NCI Genomic Data Commons file a5df293d-5492-4af1-adf0-ff0732680d2a (TCGA-4Z-AA86.B0958D4E-B2F8-4D76-96E7-714662E3B677.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).